CCDI case PBCMBU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas.
https://portal.gdc.cancer.gov/cases/d2b24b60-24e9-4277-a750-d4c6df85300d

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 16.9 years (6,187 days).

Biospecimens (3 samples)
- Sample 0DUVT8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUVTH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUVTT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
